Gene-level copy-number profile of tumor specimen TCGA-UY-A9PB-01A from TCGA case TCGA-UY-A9PB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 49.0 years (17,885 days).
Specimen TCGA-UY-A9PB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.71454bf4-b15b-41b5-ac43-8cfc3bed00a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A9PB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/992e4308-910a-4f67-9518-95de440c1bdf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 32; copy number 2: 4,728; copy number 3: 17,402; copy number 4: 12,532; copy number 5: 13,479; copy number 6: 6,338; copy number 7: 3,104; copy number 8: 1,649; copy number 9: 166; copy number 10: 106; copy number 11: 12; copy number 13: 5; copy number 15: 73; copy number 17: 20; copy number 18: 26; copy number 31: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A9PB-01A-11D-A38F-01): tumor purity 0.33, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,576,974–51,767,709, 71 genes (broad region; genes not listed).
- chr13:51,767,993–51,804,162, 1 gene: DHRS12.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,223 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:75,122,518–76,019,356, 19 genes, copy number 8: AC099786.3, AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1, AL137803.1, ACADM, DLSTP1, RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4, ASB17, AC092813.1.
- chr1:107,964,443–115,931,616, 237 genes, copy number 7 (broad region; genes not listed).
- chr1:143,343,180–151,583,583, 322 genes, copy number 8 (broad region; genes not listed).
- chr1:151,612,038–151,629,430, 2 genes, copy number 8: AL391335.1, RNU6-1062P.
- chr3:11,745–45,750,651, 693 genes, copy number 7–9 (broad region; genes not listed).
- chr3:79,957,566–90,257,415, 70 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr4:143,336,762–143,514,635, 7 genes, copy number 9: GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1.
- chr4:143,996,104–145,098,174, 10 genes, copy number 7 (within-gene range 3–7): GYPB, AC093890.2, GYPA, AC098588.3, AC098588.2, AC106871.1, KRT18P51, HHIP-AS1, HHIP, AC098588.1.
- chr5:58,198–45,895,970, 710 genes, copy number 7–10 (broad region; genes not listed).
- chr6:167,607–28,923,988, 617 genes, copy number 8 (broad region; genes not listed).
- chr7:38,291,616–38,311,808, 4 genes, copy number 17: TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:51,716,657–57,227,066, 147 genes, copy number 7 (broad region; genes not listed).
- chr8:119,557,086–128,564,679, 152 genes, copy number 8–15 (within-gene range 6–15) (broad region; genes not listed).
- chr11:95,482,406–97,657,582, 23 genes, copy number 9: AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737, AP003066.1, AP003066.2, MED28P5, AP001836.1, LINC02553, RNA5SP347.
- chr11:101,890,674–107,177,530, 91 genes, copy number 7–15 (broad region; genes not listed).
- chr12:22,699,859–23,188,807, 1 gene, copy number 8 (within-gene range 4–8): AC084816.1.
- chr12:23,108,458–32,107,528, 181 genes, copy number 8–31 (broad region; genes not listed).
- chr12:32,109,076–32,228,154, 2 genes, copy number 13: AC048344.4, AC016954.1.
- chr13:46,553,168–47,459,234, 7 genes, copy number 8: LRCH1, AL359880.1, ESD, HTR2A, HTR2A-AS1, GNG5P5, RN7SL700P.
- chr13:73,112,915–95,019,336, 223 genes, copy number 8 (broad region; genes not listed).
- chr13:109,728,282–114,337,626, 113 genes, copy number 8 (broad region; genes not listed).
- chr14:22,011,910–22,513,998, 74 genes, copy number 9 (broad region; genes not listed).
- chr17:19,403,283–20,512,357, 60 genes, copy number 8–17: AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1, AKAP10, AC005730.3, AC005730.2, SPECC1, AC005730.1, KCTD9P1, RNU6-258P, AC004702.1, RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7.
- chr20:87,250–64,313,132, 1,458 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
